MMRF case MMRF_1627 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/78eee2c8-6690-4bed-b82a-485f50da83b0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.0 years (29,968 days); ISS stage: III; Days to last known disease status: 1,262 days (3.5 years); Days to last follow up: 1,262 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 13 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 97 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 160 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days; Days to treatment end: 251 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 644 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 354 mg/dL; Immunoglobulin G 2.58 g/L; Immunoglobulin A 34.9 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 7.69 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.95 mmol/L; Albumin 33 g/L; Total Protein 8.3 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.12 mg/dL.
- Day 97 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.649 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.661 mg/dL; Immunoglobulin G 4.78 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 5.47 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 5.7 g/dL; Glucose 6.05 mmol/L.
- Day 197 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.1 g/dL; Glucose 4.46 mmol/L.
- Day 251 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 4.62 mmol/L.
- Day 342: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 8.96 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.79 mmol/L.
- Day 489 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.992 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.98 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 581 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.989 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.9 mg/dL; Immunoglobulin G 7.49 g/L; Immunoglobulin A 2.56 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 609: Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 51.3 mg/dL; Immunoglobulin G 7.3 g/L; Immunoglobulin A 2.97 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 707 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 104 mg/dL; Immunoglobulin G 5.2 g/L; Immunoglobulin A 3 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 826 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 78.6 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.4 mmol/L.
- Day 889 (ECOG 1): Hemoglobin 7.63 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 975 (ECOG 0): Hemoglobin 7.94 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 1,080 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 1,164 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.778 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.85 mg/dL; Immunoglobulin G 5.83 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 1,262 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 6.33 mmol/L.

Other clinical attributes
- Day -1: Weight: 61 kg; Height: 165 cm.

Biospecimens (3 samples)
- Sample MMRF_1627_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1627_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
- Sample MMRF_1627_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 609 days (1.7 years).
